FM case AD13531 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/0c7a7394-7d7c-4ee4-91af-d4d8e38f9bcc

Male, 44.5 years: Sarcomatoid carcinoma (ICD-O-3 8033/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
